TCGA case TCGA-XG-A823 — Pheochromocytoma and Paraganglioma (TCGA-PCPG)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Paragangliomas and Glomus Tumors; Primary site: Adrenal gland; Tissue source site: BLN UT Southwestern Medical Center at Dallas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/93fffb9e-e065-40dc-8eaa-62c9f35560c4

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Country of residence at enrollment: United States; Age at index: 25 years; Vital status: Alive.

Diagnoses (4)
1. Pheochromocytoma, malignant (the primary disease): ICD-O-3 morphology code: 8700/3; ICD-10 code: C74.9; Tissue or organ of origin: Adrenal gland, NOS; Site of resection or biopsy: Adrenal gland, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 25.0 years (9,149 days); Year of diagnosis: 2013; Prior malignancy: yes; Synchronous malignancy: Yes; Prior treatment: No; Days to last follow up: 614 days (1.7 years).
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 4.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Pheochromocytoma, NOS: ICD-O-3 morphology code: 8700/0; Tissue or organ of origin: Adrenal gland, NOS; Laterality: Left; Classification of tumor: Prior primary; Age at diagnosis: 12.1 years (4,407 days); Days to diagnosis: -4,742 days (-13.0 years).
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: -4,726 days (-12.9 years); Treatment anatomic sites: Adrenal.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Paraganglioma, NOS: ICD-O-3 morphology code: 8680/1; Tissue or organ of origin: Endocrine gland, NOS; Laterality: Right; Classification of tumor: Synchronous primary; Age at diagnosis: 25.1 years (9,155 days); Days to diagnosis: 6 days.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 6 days; Treatment anatomic sites: Adrenal.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
4. Subsequent primary of the carotid body (histology not recorded by GDC). Age at diagnosis: 25.6 years (9,339 days); Days to diagnosis: 190 days; Prior treatment: Yes.

Follow-up (4 entries)
- Day 0 (prior to diagnosis): History of tumor: Yes; History of tumor type: Phenochromocytoma or Paraganglioma.
- Days to follow up: 210 days; Disease response: Tumor Free.
- Days to follow up: 614 days (1.7 years); Disease response: Tumor Free.
- Karnofsky performance status: 90; ECOG performance status: 1; Timepoint: Post Adjuvant Therapy.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-XG-A823-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 70 mg.
  Slide TCGA-XG-A823-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 15; Percent lymphocyte infiltration: 40; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 20.
- Sample TCGA-XG-A823-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History pheo or para include benign: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: Yes.
- Primary pathology: Related tumors outside adrenal glands: Multiple tumors outside the adrenal glands; Histologic diagnosis: Pheochromocytoma; Disease detected on screening: No; Ct scan preop results: Yes; Lymph nodes examined: Yes.
- New tumor event: New tumor event type: New Primary Tumor.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; Performance status timing: Post-Adjuvant Therapy; New tumor event diagnosis indicator: No.
- Other malignancy form 1: Malignancy type: Synchronous Malignancy; Other malignancy anatomic site: Extra Adrenal Gland; Other malignancy histological type: paraganglioma; Days from index date to other malignancy diagnosis: 6.
- Other malignancy form 1, Surgery: Other malignancy surgery type: Right adrenalectomy; Days from index date to other malignancy surgery: 6.
- Other malignancy form 2: Malignancy type: Prior Malignancy; Other malignancy histological type: pheochromocytoma.
- Other malignancy form 2, Surgery: Other malignancy surgery type: adrenalectomy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 614 days; disease-specific survival: no event (censored), 614 days; disease-free interval: no event (censored), 614 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 190 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-XG-A823-01A-11D-A35H-01): tumor purity 0.56, ploidy 1.95, whole-genome doublings 0.
